Somatic mutation profile of tumor specimen TCGA-BS-A0V4-01A (aliquot TCGA-BS-A0V4-01A-11D-A14G-09) from TCGA case TCGA-BS-A0V4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 56.9 years (20,777 days).
Specimen TCGA-BS-A0V4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2e218b5-df92-4d36-8abe-141709b777cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0V4-10A (Blood Derived Normal), aliquot TCGA-BS-A0V4-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b515d65-3969-47d2-829e-511daef026e1

The open-access MAF lists 379 somatic variants for this specimen: 286 protein-altering or splice-affecting, 88 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 88, Frame Shift Del 70, Frame Shift Ins 23, Nonsense Mutation 14, Splice Site 3, Intron 3, RNA 2, Translation Start Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOA1 | c.85del p.Q29Rfs*7 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs753348565, CD961783; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 50/144 reads (35%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HPS1 | c.972dup p.M325Hfs*128 | Frame Shift Ins (INS) | VAF 26/66 reads (39%) | catalogued as rs281865082; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 21/30 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.27dup p.Q10Afs*24 | Frame Shift Ins (INS) | VAF 22/52 reads (42%) | catalogued as rs587777613; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R2 | c.1681A>G p.N561D | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1057519801, COSV55847533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 28/72 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTEN | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 32/87 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs786204859, CD110173, CM983501, COSV64288670, COSV64294671; ClinVar: pathogenic; called by muse, varscan2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- ACTRT1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as rs756223404, COSV100947557; called by muse, mutect2, varscan2
- ADAM8 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139328971; called by muse, mutect2, varscan2
- ADAM9 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV65960131; called by muse, mutect2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs746174250; called by mutect2, varscan2
- ADGRB2 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV99926022; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ANAPC5 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99946099; called by muse, mutect2, varscan2
- ANGPTL4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs557133449, COSV56844285; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs753029866; called by mutect2, varscan2
- APOB | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs148167725; called by muse, mutect2, varscan2
- ARHGAP26 | c.1989-1G>A p.X663_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as COSV50826637; called by muse, mutect2, varscan2
- ARHGAP36 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as rs778002878, COSV99357560; called by muse, mutect2, varscan2
- ARHGAP5 | c.3170A>C p.N1057T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100565182; called by muse, mutect2, varscan2
- ARHGEF17 | c.1453C>A p.L485M | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99735305; called by muse, mutect2, varscan2
- ASCC3 | c.3644C>T p.T1215I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV100225546; called by muse, mutect2, varscan2
- ATF6 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV100909123; called by muse, mutect2, varscan2
- ATP10A | c.3941C>A p.S1314Y | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.071); catalogued as rs748862225, COSV100791085; called by muse, mutect2, varscan2
- ATP9B | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100303318; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BIRC3 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV99679828; called by muse, mutect2, varscan2
- C11orf49 | c.320T>A p.L107* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99561769, COSV99561946; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- CAB39L | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs372211572; called by muse, mutect2, varscan2
- CACNA1D | c.2518C>A p.P840T (on ENST00000350061 / NM_001128840.3; = p.P860T on NM_000720.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV99857543; called by muse, mutect2, varscan2
- CALCRL | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV66476027; called by muse, mutect2
- CAMKK2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV61214015; called by muse, mutect2, varscan2
- CAMSAP3 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV99350374; called by muse, varscan2
- CBY2 | c.1337G>A p.S446N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.215); catalogued as COSV100137566; called by muse, mutect2, varscan2
- CCDC173 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV101506319; called by muse, mutect2, varscan2
- CCDC180 | c.4613C>T p.P1538L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs367588606, COSV100826642; called by muse, mutect2, varscan2
- CCDC62 | c.1043del p.N348Ifs*45 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1412762139; called by mutect2, pindel, varscan2
- CCDC97 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as COSV99523678; called by muse, mutect2, varscan2
- CCDC9B | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101233500; called by muse, mutect2, varscan2
- CCL23 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs202213083; called by muse, mutect2, varscan2
- CCNT1 | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as rs752671890, COSV99980668; called by muse, mutect2, varscan2
- CDC42BPB | c.1858C>T p.R620W | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761404232, COSV100775352; called by muse, mutect2, varscan2
- CELF4 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs774068000, COSV58449209; called by mutect2, varscan2
- CFAP47 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99934832; called by muse, mutect2, varscan2
- CIB2 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV99363186; called by muse, mutect2, varscan2
- CLDN10 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1438067157, COSV54823904; called by muse, mutect2, varscan2
- CLMN | c.2610T>G p.H870Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100112293; called by muse, mutect2, varscan2
- CNNM2 | c.2138A>G p.Y713C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100881784; called by muse, mutect2, varscan2
- COL11A1 | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1337462128, COSV100615964, COSV62184879; called by muse, mutect2, varscan2
- CRAMP1 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs577488354, COSV51960064; called by muse, mutect2, varscan2
- CRELD1 | c.533G>C p.S178T | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV99926451; called by muse, mutect2, varscan2
- CSMD3 | c.8453G>A p.G2818E (on ENST00000297405 / NM_001363185.1; = p.G2649E on NM_052900.3) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99831081; called by muse, mutect2, varscan2
- CTR9 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1397467879, COSV63727972; called by muse, mutect2, varscan2
- CYFIP1 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.329); catalogued as rs1486160282; called by muse, mutect2, varscan2
- DAPP1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776332284, COSV99596780; called by muse, mutect2, varscan2
- DBX2 | c.734A>T p.K245I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100224282; called by muse, mutect2, varscan2
- DDR2 | c.1560C>A p.H520Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100906429; called by muse, mutect2, varscan2
- DENND2A | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99325464, COSV99325902; called by muse, mutect2, varscan2
- DGKZ | c.3110dup p.E1038Rfs*4 (on ENST00000454345 / NM_001105540.2; = p.E850Rfs*4 on NM_003646.4) | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs3832759; called by mutect2, varscan2
- DIAPH3 | c.2695A>G p.N899D (on ENST00000400324 / NM_001042517.2; = p.N636D on NM_030932.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV99933220; called by muse, mutect2, varscan2
- DLC1 | c.790_793del p.N264Efs*6 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs761189123; called by mutect2, varscan2
- DMBT1 | c.5915A>G p.D1972G (on ENST00000338354 / NM_001377530.1; = p.D1215G on NM_004406.3) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.234); catalogued as rs1239247200, COSV100352665; called by muse, mutect2, varscan2
- DNAH2 | c.2965G>A p.A989T | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as COSV101209173; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 51/82 reads (62%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOP1B | c.6227del p.F2076Sfs*6 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as rs34641375; called by mutect2, pindel, varscan2
- DPY19L1 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs569347879, COSV60584251; called by muse, mutect2, varscan2
- DST | c.4945G>A p.A1649T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99754173; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs750962255; called by mutect2, varscan2
- DYNC1I1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100268054; called by muse, mutect2, varscan2
- DYNC1LI2 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262977; called by muse, mutect2, varscan2
- DYNC2I1 | c.2878C>A p.L960M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV101337650; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs748937918; called by mutect2, varscan2
- ELANE | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.474); catalogued as CM078496, COSV99708672, COSV99708695; called by muse, mutect2, varscan2
- ELAPOR1 | c.2973+2T>C p.X991_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100884425; called by muse, mutect2, varscan2
- ELFN2 | c.1388C>A p.P463H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV101297526; called by muse, mutect2, varscan2
- ELMO1 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476363678, COSV60298034, COSV60325791; called by muse, mutect2, varscan2
- EMILIN2 | c.508del p.V170* | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1281163907; called by mutect2, pindel, varscan2
- ESR1 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99238680; called by muse, mutect2, varscan2
- EXOSC10 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760738154, COSV58665021; called by muse, mutect2, varscan2
- F8 | c.5122del p.R1708Afs*23 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs1209671783, CD1212743, CM1314171, CM880026; called by mutect2, pindel, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | catalogued as rs766589051; called by mutect2, varscan2
- FARSA | c.437del p.G146Dfs*14 | Frame Shift Del (DEL) | VAF 40/95 reads (42%) | catalogued as rs746493788; called by mutect2, pindel, varscan2
- FBXO24 | c.131dup p.E45Rfs*106 (on ENST00000241071 / NM_033506.3; = p.E83Rfs*106 on NM_012172.5) | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | catalogued as rs1311766618; called by mutect2, pindel, varscan2
- FBXO34 | c.1454dup p.L485Ffs*15 | Frame Shift Ins (INS) | VAF 17/51 reads (33%) | catalogued as rs759373712; called by mutect2, varscan2
- FCHSD2 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280562098, COSV100238151; called by muse, mutect2, varscan2
- FHOD3 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs544989871, COSV99940820; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FKRP | c.1483G>T p.G495C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.189); catalogued as rs759929539, COSV100586675; called by muse, mutect2, varscan2
- FLNC | c.3244C>T p.P1082S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV100367918; called by muse, mutect2, varscan2
- FRAS1 | c.10464del p.R3489Gfs*39 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs1560423717, COSV99351879; called by mutect2, pindel, varscan2
- FRMD4A | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99198468; called by muse, mutect2
- GGA1 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.697); catalogued as COSV100289701; called by muse, mutect2
- GOLGA3 | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99202529; called by muse, mutect2, varscan2
- GRIP2 | c.3029G>A p.R1010Q (on ENST00000619221; = p.R913Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs371134453; called by muse, mutect2, varscan2
- GRM1 | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99265408; called by muse, mutect2, varscan2
- HAP1 | c.1664C>T p.T555M (on ENST00000310778 / NM_001367460.1; = p.T503M on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.238); catalogued as rs138660137; called by muse, mutect2
- HAUS7 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.639); catalogued as COSV100444066; called by muse, mutect2, varscan2
- HCRTR1 | c.691A>G p.M231V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV101036185; called by muse, mutect2, varscan2
- HDAC11 | c.291dup p.V98Rfs*70 | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | catalogued as rs754533859; called by mutect2, varscan2
- HDAC4 | c.2509G>A p.V837M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs768337069, COSV100613167; called by muse, mutect2, varscan2
- HIF3A | c.680C>A p.P227H (on ENST00000377670 / NM_152795.4; = p.P158H on NM_022462.4) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355689; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs755016625; called by mutect2, varscan2
- IFI44L | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV100654958; called by muse, mutect2, varscan2
- INSRR | c.1970G>A p.C657Y | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1228589582, COSV100947369; called by muse, mutect2, varscan2
- ITGB5 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV99950561; called by muse, mutect2, varscan2
- JMJD1C | c.3161C>T p.S1054L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100550395; called by muse, mutect2, varscan2
- KCNK15 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs745470934, COSV100865102; called by muse, mutect2
- KCNU1 | c.2498C>A p.S833Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV101299116; called by muse, mutect2, varscan2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs759860142; called by mutect2, pindel, varscan2
- KCTD8 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as COSV99077647; called by muse, mutect2, varscan2
- KDM1B | c.1108G>T p.G370* (on ENST00000449850; = p.G238* on NM_153042.4) | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99924156; called by muse, mutect2, varscan2
- KIAA1217 | c.463del p.D155Mfs*19 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as rs1264299382; called by mutect2, pindel, varscan2
- KIF1C | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV100297059; called by muse, mutect2, varscan2
- KIF1C | c.2850G>T p.Q950H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV100297060; called by muse, varscan2
- KIF24 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV99903040; called by muse, mutect2, varscan2
- KMT2B | c.6549_6550insTA p.P2184Yfs*20 | Frame Shift Ins (INS) | VAF 18/61 reads (30%) | catalogued as COSV99719290; called by mutect2, pindel
- KRT6B | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99360631; called by muse, mutect2, varscan2
- LANCL3 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV66128593; called by muse, mutect2, varscan2
- LHX6 | c.694C>T p.Q232* (on ENST00000373755 / NM_001242334.2; = p.Q261* on NM_014368.5) | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100493328; called by muse, mutect2, varscan2
- LPA | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as COSV100306581; called by muse, mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs762083435; called by mutect2, varscan2
- LVRN | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.757); catalogued as rs138090918, COSV63496673; called by muse, mutect2, varscan2
- LYST | c.9986G>A p.W3329* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV101087861, COSV101088992; called by muse, mutect2
- MAGEB1 | c.573T>G p.N191K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.216); catalogued as COSV100974922; called by muse, mutect2, varscan2
- MAML2 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs902678649, COSV101594088; called by muse, mutect2, varscan2
- MBLAC2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs762371522, COSV100353083; called by muse, mutect2, varscan2
- METTL2B | c.887A>G p.Y296C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1346339708, COSV52309951; called by muse, mutect2, varscan2
- MFSD14A | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776735546, COSV64514594; called by muse, mutect2, varscan2
- MLLT10 | c.161-2A>T p.X54_splice | Splice Site (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100307887; called by muse, mutect2, varscan2
- MLX | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745504523, COSV99518890; called by muse, mutect2, varscan2
- MNT | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as rs372107997; called by muse, mutect2, varscan2
- MOB3C | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147799654; called by muse, mutect2, varscan2
- MTHFSD | c.247del p.T83Hfs*9 (on ENST00000360900 / NM_001159377.2; = p.T82Hfs*9 on NM_022764.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | catalogued as rs1266793672; called by mutect2, pindel, varscan2
- MTMR3 | c.1674C>T p.A558= | Splice Region (SNP) | VAF 31/92 reads (34%) | catalogued as rs1045389809, COSV60306932; called by muse, mutect2, varscan2
- MYOF | c.3218G>A p.R1073H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755201286, COSV100825559; called by muse, mutect2, varscan2
- MYRF | c.789dup p.S264Qfs*74 (on ENST00000278836 / NM_001127392.3; = p.S255Qfs*74 on NM_013279.4) | Frame Shift Ins (INS) | VAF 16/72 reads (22%) | catalogued as rs769274302; called by mutect2, varscan2
- MZT2B | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1043073, COSV56058157; called by muse, mutect2, varscan2
- NAV1 | c.3829G>T p.G1277C | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.912); catalogued as COSV99818588; called by muse, mutect2, varscan2
- NCAPH | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV99545740; called by muse, mutect2, varscan2
- NDST1 | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55790574; called by muse, mutect2
- NES | c.2714C>G p.S905C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as rs772116906, COSV63960731; called by muse, varscan2
- NFKB1 | c.2008C>G p.L670V (on ENST00000394820 / NM_001382627.1; = p.L671V on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV99896958; called by muse, mutect2, varscan2
- NPHP4 | c.3896G>A p.G1299D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532503870, COSV100976830; called by muse, mutect2, varscan2
- NRIP2 | c.74_75del p.R25Tfs*36 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs750711688; called by pindel, varscan2
- NSL1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209586180, COSV100875511; called by muse, mutect2, varscan2
- OCLN | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV100783808; called by mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR6K2 | c.940dup p.S314Ffs*9 | Frame Shift Ins (INS) | VAF 22/57 reads (39%) | catalogued as rs764050222; called by mutect2, varscan2
- OR6K3 | c.142C>T p.L48F (on ENST00000368146; = p.L32F on NM_001005327.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as rs773001694, COSV63746735; called by muse, varscan2
- OR8B2 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV100899371; called by muse, mutect2, varscan2
- ORAI2 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.728); catalogued as COSV100709910; called by muse, mutect2, varscan2
- OSBPL10 | c.1464C>A p.H488Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV67340963, COSV67342553; called by muse, mutect2, varscan2
- OSGEP | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52831337; called by muse, mutect2, varscan2
- OSR1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.391); catalogued as rs1436842858, COSV99693618; called by muse, mutect2, varscan2
- OTUD6A | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 30/61 reads (49%) | catalogued as COSV100610968; called by muse, mutect2, varscan2
- PARD3 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as rs757021288, COSV100400752; called by muse, mutect2, varscan2
- PCDHB1 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100128126; called by muse, mutect2, varscan2
- PCDHB12 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs139448614, COSV99507114; called by muse, mutect2, varscan2
- PCDHGA5 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as rs1474350947, COSV99535463; called by muse, mutect2, varscan2
- PDZRN4 | c.2489T>C p.L830P (on ENST00000402685 / NM_001164595.2; = p.L572P on NM_013377.4) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.806); catalogued as COSV100114186; called by muse, mutect2, varscan2
- PGAP4 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV100877814; called by muse, mutect2, varscan2
- PHC2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99930918; called by muse, mutect2, varscan2
- PHF24 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV99646014; called by muse, mutect2, varscan2
- PLXND1 | c.2779G>A p.V927M | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs140355020, COSV100139488; called by muse, mutect2, varscan2
- PPM1B | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs761929900, COSV99175749; called by muse, mutect2, varscan2
- PPP4R1 | c.2405A>G p.Y802C (on ENST00000400556 / NM_001042388.3; = p.Y785C on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV99553366; called by muse, mutect2, varscan2
- PRUNE2 | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.191); catalogued as COSV100944434; called by muse, mutect2, varscan2
- PTPRD | c.3185_3187del p.E1062del | In Frame Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs1282828198; called by pindel, varscan2
- PTPRJ | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV101394848; called by muse, mutect2
- PTPRR | c.1313dup p.N438Kfs*11 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | catalogued as rs1424153094; called by mutect2, pindel, varscan2
- PTPRZ1 | c.5083G>T p.D1695Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101099919; called by muse, mutect2, varscan2
- RAD23A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100330579, COSV57132700; called by muse, mutect2, varscan2
- RAG1 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100200821; called by muse, mutect2, varscan2
- RBM46 | c.1339A>T p.K447* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99908023; called by muse, mutect2, varscan2
- RDH8 | c.988C>T p.P330S (on ENST00000651512; = p.P310S on NM_015725.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs200512922, COSV99408615; called by muse, mutect2, varscan2
- RESF1 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs1485029320, COSV100440268; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF17 | c.4835C>T p.P1612L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.232); catalogued as COSV99692820; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 40/121 reads (33%) | catalogued as rs757272743; called by mutect2, pindel, varscan2
- RPS6KA5 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as COSV100002434; called by muse, mutect2, varscan2
- RXRG | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 90/187 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs1185289848, COSV100717420; called by muse, mutect2, varscan2
- SALL4 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759061679, COSV53851038; called by muse, mutect2, varscan2
- SDCBP2 | c.379G>A p.D127N (on ENST00000339987 / NM_001199784.1; = p.D42N on NM_015685.5) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV60589402; called by muse, mutect2, varscan2
- SDK2 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs370423133; called by muse, mutect2, varscan2
- SEC16A | c.1781C>A p.P594Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99257306; called by muse, mutect2, varscan2
- SERPINF2 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100131879; called by muse, mutect2, varscan2
- SGMS1 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100693285; called by muse, mutect2
- SHROOM2 | c.2075T>C p.L692P | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051394097, COSV101098423; called by muse, mutect2, varscan2
- SKIV2L | c.2446del p.E816Rfs*3 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs768446878; called by mutect2, pindel, varscan2
- SLC12A7 | c.2056dup p.H686Pfs*230 | Frame Shift Ins (INS) | VAF 47/151 reads (31%) | catalogued as rs767964038; called by mutect2, varscan2
- SLC2A8 | c.1424A>T p.E475V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV100972622; called by muse, mutect2, varscan2
- SLC39A4 | c.950T>A p.V317D (on ENST00000301305 / NM_001374839.1; = p.V292D on NM_017767.3) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV99433227; called by muse, mutect2, varscan2
- SLC6A8 | c.1388C>T p.T463I | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99465876; called by muse, mutect2, varscan2
- SLFN5 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs746380879, COSV55479605; called by muse, mutect2, varscan2
- SLITRK3 | c.2627G>C p.G876A | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.85); PolyPhen probably damaging (0.91); catalogued as COSV53845814, COSV99578942, COSV99580309; called by muse, mutect2, varscan2
- SMG5 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.061); catalogued as rs376384052; called by muse, mutect2, varscan2
- SP140L | c.1385A>G p.E462G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99707005; called by muse, mutect2, varscan2
- SPAG17 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs750605549, COSV60463634; called by muse, mutect2, varscan2
- SPECC1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.638); catalogued as rs865807674, COSV99821682; called by muse, mutect2, varscan2
- SPEM2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747765542, COSV60366376; called by muse, mutect2, varscan2
- SZT2 | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as rs1281142385, COSV100987096; called by muse, mutect2, varscan2
- TAF1 | c.2546G>A p.R849H (on ENST00000373790 / NM_138923.4; = p.R870H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52108870; called by muse, mutect2, varscan2
- TFR2 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV99774455; called by muse, mutect2, varscan2
- TFRC | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as rs1048486099, COSV100786434; called by muse, mutect2, varscan2
- THEM4 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100916921; called by muse, mutect2, varscan2
- TLE3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs767037525, COSV100450265; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.226); catalogued as rs1455222857, COSV99143269; called by muse, mutect2, varscan2
- TMEM101 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs141703439; called by muse, mutect2, varscan2
- TMEM119 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as rs372101981; called by muse, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNRC6A | c.1616G>A p.G539D | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100169738; called by muse, mutect2, varscan2
- TRABD2A | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100119801; called by muse, mutect2, varscan2
- TRAPPC11 | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV100591806; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 32/72 reads (44%) | catalogued as rs752676391; called by mutect2, varscan2
- TSC1 | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100051589; called by muse, mutect2, varscan2
- TTC38 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101123876; called by muse, mutect2, varscan2
- TTN | c.46184C>G p.A15395G (on ENST00000591111; = p.A7971G on NM_003319.4) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | PolyPhen benign (0.116); catalogued as COSV100605062; called by muse, mutect2, varscan2
- UHMK1 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99966203; called by muse, mutect2, varscan2
- UNC5C | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV101497858; called by muse, mutect2, varscan2
- USP31 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV99564970; called by muse, mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VGLL1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV101034592; called by muse, mutect2, varscan2
- VMA21 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100377742; called by muse, mutect2, varscan2
- VWA3B | c.3257del p.G1086Afs*19 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs753015649; called by mutect2, pindel, varscan2
- WASHC5 | c.121A>G p.R41G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100572746; called by muse, mutect2, varscan2
- WWP1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99616112; called by muse, mutect2, varscan2
- ZBTB2 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as rs775998685, COSV57313924; called by muse, mutect2, varscan2
- ZC3H14 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs766543804, COSV51768166; called by muse, mutect2, varscan2
- ZC3H3 | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99367685; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs563751025; called by mutect2, varscan2
- ZNF536 | c.2480G>A p.S827N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100835030; called by muse, mutect2, varscan2
- ZNF776 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV100414138; called by muse, mutect2, varscan2
- ZNHIT6 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.037); catalogued as COSV100995565; called by muse, mutect2, varscan2
- ADCY9 | c.3965del p.G1322Vfs*7 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, varscan2
- AGAP1 | c.1560del p.S521Pfs*83 (on ENST00000304032 / NM_001037131.3; = p.S468Pfs*83 on NM_014914.5) | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- ARID1A | c.4266_4273del p.P1423Rfs*19 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- ARID4B | c.3333del p.A1112Pfs*8 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- BAG4 | c.1147dup p.I383Nfs*12 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- BEND3 | c.793del p.D265Tfs*54 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- BICRA | c.3716del p.P1239Lfs*9 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- CEP152 | c.3829del p.I1277Lfs*20 (on ENST00000380950 / NM_001194998.2; = p.I1221Lfs*20 on NM_014985.4) | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- CNTN6 | c.1638del p.G547Efs*16 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- DYSF | c.5880del p.F1960Lfs*6 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.754del p.L252Cfs*22 | Frame Shift Del (DEL) | VAF 48/128 reads (38%) | called by mutect2, pindel, varscan2
- ELF4 | c.1931del p.P644Qfs*45 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- EXOSC9 | c.234del p.F78Lfs*23 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, varscan2
- GALC | c.1884del p.K628Nfs*7 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- HECW2 | c.1146dup p.K383Qfs*7 | Frame Shift Ins (INS) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- HSD11B1 | c.387dup p.H130Sfs*2 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- HSPA12A | c.1522del p.Q508Rfs*32 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- IL23R | c.152_153dup p.C52Ifs*63 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- IRF2 | c.500del p.N167Mfs*7 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- LCT | c.3477del p.F1159Lfs*10 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- LRRC37A2 | c.3116G>A p.C1039Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- MID2 | c.1061dup p.N354Kfs*4 | Frame Shift Ins (INS) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- MTA1 | c.1913del p.G638Afs*11 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | called by mutect2, pindel, varscan2
- NEB | c.10325del p.N3442Tfs*4 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- NSD1 | c.4591del p.M1531Cfs*43 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- NSMCE2 | c.545dup p.N182Kfs*2 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- OR2M4 | c.452dup p.L151Ffs*5 | Frame Shift Ins (INS) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- PEG3 | c.329del p.K110Sfs*29 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- PHF2 | c.1675del p.M559Wfs*14 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, varscan2
- PID1 | c.179del p.K60Rfs*23 (on ENST00000354069 / NM_001330156.1; = p.K58Rfs*23 on NM_017933.5) | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- PIGO | c.1841del p.P614Hfs*9 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, pindel, varscan2
- PLEKHO1 | c.739dup p.T247Nfs*46 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- PRCC | c.1138del p.Q380Rfs*47 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, varscan2
- PUS7 | c.96del p.K32Nfs*9 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- RANBP1 | c.457del p.T153Qfs*32 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- RFX5 | c.56del p.P19Qfs*28 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- SCAF4 | c.359del p.N120Mfs*25 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- SETX | c.4877del p.N1626Ifs*10 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- STAC2 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2
- SUSD4 | c.1235del p.P412Qfs*51 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- SYBU | c.1267del p.E423Kfs*9 (on ENST00000276646 / NM_001099754.2; = p.E422Kfs*9 on NM_017786.6) | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- TAF15 | c.1694dup p.Y566Lfs*21 (on ENST00000605844 / NM_139215.3; = p.Y563Lfs*21 on NM_003487.4) | Frame Shift Ins (INS) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.7939del p.R2647Gfs*44 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- ZKSCAN2 | c.970dup p.T324Nfs*13 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- ZNF398 | c.1194del p.T399Pfs*68 (on ENST00000475153 / NM_170686.3; = p.T228Pfs*68 on NM_020781.4) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- AATK | c.3045C>T p.C1015= (on ENST00000326724 / NM_001080395.3; = p.C912= on NM_004920.2) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs775382756, COSV100352699; called by muse, mutect2, varscan2
- ABCB1 | c.3264C>T p.D1088= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99712670; called by muse, mutect2, varscan2
- ACTN3 | c.2649T>C p.A883= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100074223, COSV59749259; called by muse, mutect2, varscan2
- ACTR6 | c.522T>C p.N174= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99498563; called by muse, mutect2, varscan2
- ACTRT3 | c.894G>A p.G298= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100377407; called by muse, mutect2, varscan2
- ADPRH | c.747C>T p.F249= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs148728137, COSV100813365; called by muse, mutect2, varscan2
- AGTPBP1 | c.321C>A p.T107= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100429327; called by muse, mutect2
- ANGPT1 | c.1155C>A p.A385= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99862516; called by muse, mutect2, varscan2
- ANXA2 | c.372C>T p.D124= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs748528078, COSV100221948; called by muse, mutect2, varscan2
- ARHGEF11 | c.4551C>T p.A1517= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs756128477, COSV100168471; called by muse, mutect2, varscan2
- ARPIN | c.630G>A p.A210= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as rs1012569932, COSV100673445; called by muse, mutect2, varscan2
- ATP7A | c.2655T>C p.P885= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs781976106, COSV100430609; called by muse, mutect2, varscan2
- BCORL1 | c.2295G>A p.T765= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs920734660, COSV54408085; called by muse, mutect2, varscan2
- BCR | c.2355C>T p.D785= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs776602598, COSV100006343; called by muse, mutect2, varscan2
- C20orf194 | c.3298C>T p.L1100= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99330568; called by muse, mutect2, varscan2
- CCNA1 | c.970C>T p.L324= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99714488; called by muse, mutect2, varscan2
- CDKL5 | c.2388C>T p.S796= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs727503847, CD1414961, COSV101184233; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- CEP350 | c.450C>T p.H150= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs367691403; called by muse, mutect2
- CEP68 | c.490C>T p.L164= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99560823; called by muse, mutect2, varscan2
- CHST5 | c.177C>T p.G59= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs371668265; called by muse, mutect2, varscan2
- CLCNKA | c.822C>T p.D274= | Silent (SNP) | VAF 51/199 reads (26%) | catalogued as rs1323285803, COSV100510000, COSV58891138; called by muse, mutect2, varscan2
- CRISPLD1 | c.99G>A p.E33= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100081812, COSV100082100; called by muse, mutect2, varscan2
- CYP4F2 | c.1176T>C p.H392= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV55622067; called by muse, mutect2, varscan2
- DAAM2 | c.351G>A p.A117= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs746263836, COSV99225330; called by muse, mutect2, varscan2
- DLL1 | c.1341C>T p.C447= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs369504757; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH2 | c.8190G>A p.V2730= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101209174; called by muse, mutect2, varscan2
- EFHC1 | c.1620G>A p.A540= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs773438652, COSV64137156; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGFR | c.2166G>A p.A722= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs367694667; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERICH3 | c.3594C>T p.S1198= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100443958; called by muse, mutect2, varscan2
- ESD | c.513A>G p.A171= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1345892609, COSV101099118; called by muse, mutect2
- FAM71B | c.1392G>A p.A464= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as rs368867239, COSV57231484; called by muse, mutect2, varscan2
- FMNL3 | c.2604C>T p.S868= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs774075795, COSV53305179; called by muse, mutect2, varscan2
- FUCA2 | c.582T>C p.D194= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99136024; called by muse, mutect2, varscan2
- GAL3ST4 | c.1266C>T p.R422= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs573489011, COSV100385438; called by muse, mutect2, varscan2
- GALR1 | c.786G>A p.P262= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs767721887, COSV100231776; called by muse, mutect2, varscan2
- GLI2 | c.1137C>T p.T379= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1319332957, COSV58034087; called by muse, mutect2, varscan2
- GPC3 | c.945C>T p.D315= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100892924; called by muse, mutect2, varscan2
- GRN | c.1755G>A p.R585= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99274740; called by muse, mutect2, varscan2
- GTSE1 | c.909G>A p.A303= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs753934434, COSV71890200; called by muse, mutect2, varscan2
- GUCY2F | c.1554C>A p.P518= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99484811; called by muse, mutect2, varscan2
- HEMK1 | c.402G>A p.R134= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99231654; called by muse, mutect2, varscan2
- HMCN2 | c.2293C>A p.R765= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs374761776; called by muse, mutect2, varscan2
- HOXA1 | c.429C>T p.H143= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1294382581, COSV99761141; called by muse, mutect2, varscan2
- IGFN1 | c.1734T>C p.I578= (on ENST00000295591 / NM_001367841.1; = p.I3035= on NM_001164586.2) | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV99811873; called by muse, mutect2, varscan2
- IGSF3 | c.3180G>A p.P1060= (on ENST00000369486 / NM_001007237.3; = p.P1080= on NM_001542.4) | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs202172819, COSV100605038, COSV59590853; called by muse, mutect2, varscan2
- ITIH4 | c.828C>A p.V276= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV99819187; called by muse, mutect2, varscan2
- KCMF1 | c.357C>T p.G119= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as COSV69054820; called by muse, mutect2, varscan2
- KCNT1 | c.1365C>T p.R455= (on ENST00000488444; = p.R474= on NM_020822.3) | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs372250372; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- KIF21B | c.147C>A p.T49= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100144296; called by muse, mutect2, varscan2
- KRT28 | c.1075C>T p.L359= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100137487; called by muse, mutect2, varscan2
- LRTM2 | c.807C>T p.C269= | Silent (SNP) | VAF 41/57 reads (72%) | catalogued as COSV99765449; called by muse, mutect2, varscan2
- LTBP2 | c.1302G>A p.P434= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs759477074, COSV56205728; called by muse, mutect2, varscan2
- MAP9 | c.294C>T p.N98= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs774661156, COSV100250847; called by muse, mutect2, varscan2
- MEGF11 | c.2991G>T p.V997= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99987424; called by muse, mutect2, varscan2
- MMACHC | c.444G>A p.V148= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV99423540; called by muse, mutect2, varscan2
- NEK9 | c.297G>A p.E99= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99463906; called by muse, mutect2, varscan2
- ONECUT1 | c.780C>T p.G260= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100009141; called by muse, mutect2, varscan2
- PCDHB6 | c.2370C>T p.S790= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99170042; called by muse, mutect2, varscan2
- PDE11A | c.522G>A p.A174= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs760047687, COSV99611605; called by muse, mutect2, varscan2
- PIK3CG | c.15C>T p.N5= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100782786; called by muse, mutect2, varscan2
- PLK3 | c.876C>T p.A292= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs141393412; called by muse, mutect2, varscan2
- PLXNA1 | c.531A>G p.P177= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99302772; called by muse, mutect2, varscan2
- POLM | c.1170C>T p.C390= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV99641750; called by muse, mutect2, varscan2
- PRMT7 | c.1227C>T p.S409= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs879076506, COSV59834812; called by muse, mutect2, varscan2
- RAB11B | c.273C>T p.Y91= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs550984439, COSV100033030; called by muse, varscan2
- RAPH1 | c.1407G>A p.V469= (on ENST00000319170 / NM_213589.3; = p.V521= on NM_203365.4) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs756009318, COSV100051360; called by muse, mutect2, varscan2
- ROR2 | c.2409C>A p.P803= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100995723; called by muse, mutect2, varscan2
- SCN11A | c.813T>C p.G271= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100181329; called by muse, mutect2, varscan2
- SDHC | c.99G>A p.T33= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs145535502, COSV100713636; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SEPTIN14 | c.1176C>T p.L392= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs764910450, COSV66431685; called by muse, mutect2, varscan2
- SLC28A3 | c.1842C>T p.S614= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100883215; called by muse, mutect2, varscan2
- SMPD4 | c.1479C>T p.R493= (on ENST00000409031 / NM_017951.4; = p.R464= on NM_017751.4) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100302398; called by muse, mutect2, varscan2
- SNRK | c.1764T>C p.N588= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99939014; called by muse, mutect2, varscan2
- SNRNP35 | c.687G>A p.R229= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100644557; called by muse, mutect2, varscan2
- SYMPK | c.1860C>T p.F620= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs779782775, COSV55610759; called by muse, mutect2, varscan2
- TAS2R38 | c.381C>T p.T127= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV101516396, COSV101516534; called by muse, mutect2, varscan2
- TEAD3 | c.1065C>T p.N355= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs995749355, COSV100132360; called by muse, mutect2, varscan2
- TEAD3 | c.906C>T p.D302= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100132361, COSV58816927; called by muse, mutect2, varscan2
- TMEM132D | c.1347C>T p.A449= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs189348668; called by muse, mutect2, varscan2
- TMEM132E | c.867G>A p.L289= (on ENST00000321639; = p.L379= on NM_001304438.2) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100396103; called by muse, mutect2, varscan2
- TMEM25 | c.999G>A p.P333= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs201232329, COSV100244753; called by muse, mutect2
- TNS1 | c.4701G>A p.K1567= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs1332406761, COSV99410369; called by muse, mutect2, varscan2
- TP73 | c.366C>T p.P122= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs1248181369, COSV100601104; called by muse, mutect2, varscan2
- VAMP7 | c.525C>T p.S175= | Silent (SNP) | VAF 141/378 reads (37%) | catalogued as COSV99387813; called by muse, mutect2, varscan2
- VARS1 | c.408C>T p.G136= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs752958092, COSV100989544; called by muse, mutect2, varscan2
- VWA3A | c.906C>T p.C302= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs745685320, COSV100240792; called by muse, mutect2, varscan2
- ZNF133 | c.882T>C p.G294= (on ENST00000316358 / NM_001352454.2; = p.G293= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100315406; called by muse, mutect2, varscan2
- ZNF8 | c.1338A>G p.E446= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99544223; called by muse, mutect2, varscan2
- BX119917.1 | n.121G>T | RNA (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- GCNT2 | c.925+27347del | Intron (DEL) | VAF 9/20 reads (45%) | called by mutect2, pindel, varscan2
- NRG1 | c.502+31395C>T | Intron (SNP) | VAF 72/162 reads (44%) | catalogued as rs199722954, COSV55154774; called by muse, mutect2, varscan2
- RTEL1 | c.3652+69G>T | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99422889; called by muse, mutect2, varscan2
- SSPOP | n.5628G>A | RNA (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100022359; called by muse, mutect2, varscan2
